Somatic mutation profile of tumor specimen TCGA-CV-7242-01A (aliquot TCGA-CV-7242-01A-11D-2012-08) from TCGA case TCGA-CV-7242, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.6 years (22,136 days).
Specimen TCGA-CV-7242-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91e68d90-4966-415c-a973-ce4efcbb7b6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7242-10A (Blood Derived Normal), aliquot TCGA-CV-7242-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98a00d03-35a7-429a-b1f7-73b2b3c9e778

The open-access MAF lists 321 somatic variants for this specimen: 253 protein-altering or splice-affecting, 63 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 63, Nonsense Mutation 17, Splice Site 7, Frame Shift Del 7, Splice Region 3, RNA 2, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 32/87 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.765A>T p.G255= | Splice Region (SNP) | VAF 32/110 reads (29%) | catalogued as COSV100741740; called by muse, mutect2, varscan2
- ABAT | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99190914; called by muse, mutect2, varscan2
- ABCA10 | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.637); catalogued as COSV99288275; called by muse, mutect2, varscan2
- ABCB4 | c.2101C>A p.L701M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.208); catalogued as COSV99710069; called by muse, mutect2, varscan2
- ABCG8 | c.1884+2T>A p.X628_splice | Splice Site (SNP) | VAF 22/108 reads (20%) | catalogued as COSV99699622; called by muse, mutect2, varscan2
- ACTRT2 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV101007574; called by muse, mutect2, varscan2
- ACVR1 | c.1511A>T p.K504I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99717666; called by mutect2, varscan2
- ADH7 | c.428C>A p.T143K | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV99265156; called by muse, mutect2, varscan2
- AHI1 | c.3338A>C p.Q1113P | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV99662358; called by muse, mutect2
- AHNAK | c.17536G>T p.G5846C | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV99946601; called by muse, mutect2, varscan2
- AHSA1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.981); catalogued as COSV53632026; called by muse, mutect2, varscan2
- AKAP12 | c.3951T>A p.D1317E | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV99482878; called by muse, mutect2, varscan2
- AKAP9 | c.9701T>G p.L3234* (on ENST00000359028; = p.L3210* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/51 reads (8%) | catalogued as COSV100662194; called by muse, mutect2
- AL121899.2 | c.2077G>C p.D693H | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); catalogued as COSV101198425; called by muse, mutect2, varscan2
- ALMS1 | c.9955A>C p.T3319P | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52506365; called by muse, mutect2, varscan2
- ANKS4B | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.357); catalogued as COSV100289767; called by muse, mutect2, varscan2
- APBB1IP | c.743C>G p.T248R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100770884; called by muse, mutect2, varscan2
- APOB | c.7816G>A p.A2606T | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99264753; called by muse, mutect2, varscan2
- ARHGEF18 | c.1214A>T p.E405V (on ENST00000359920 / NM_001130955.2; = p.E301V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV100149321; called by muse, mutect2, varscan2
- ATR | c.6956G>A p.G2319E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100637945; called by muse, mutect2, varscan2
- BAZ2B | c.4841C>T p.P1614L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV58605965; called by muse, mutect2, varscan2
- BNIP5 | c.966G>A p.W322* | Nonsense Mutation (SNP) | VAF 17/119 reads (14%) | catalogued as COSV101465132; called by muse, mutect2, varscan2
- C3orf20 | c.1691-1G>T p.X564_splice | Splice Site (SNP) | VAF 20/58 reads (34%) | catalogued as rs528772163, COSV99513670; called by muse, mutect2, varscan2
- CADPS2 | c.1250C>A p.T417N | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100461851; called by muse, mutect2, varscan2
- CALCOCO1 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | catalogued as rs768996469, COSV100017240; called by muse, mutect2, varscan2
- CAMTA1 | c.2896G>T p.D966Y | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100347980; called by muse, mutect2, varscan2
- CARM1 | c.1721C>T p.T574M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.374); catalogued as rs139191688; called by muse, mutect2, varscan2
- CASP8AP2 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV99386910; called by muse, mutect2, varscan2
- CATSPER2 | c.1044G>T p.R348S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs754225338, COSV100390652; called by muse, mutect2, varscan2
- CCDC158 | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66357568; called by muse, mutect2, varscan2
- CCDC27 | c.1829A>T p.D610V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV99622293; called by muse, mutect2, varscan2
- CCDC40 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.133); catalogued as COSV99481569; called by muse, mutect2, varscan2
- CEP170 | c.538C>G p.P180A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100316777; called by muse, mutect2, varscan2
- CFH | c.3233G>T p.R1078M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as COSV100809216; called by muse, mutect2, varscan2
- CHD6 | c.1439A>G p.K480R | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.124); catalogued as COSV100497994; called by muse, mutect2, varscan2
- CHFR | c.886G>A p.D296N (on ENST00000432561 / NM_001161345.1; = p.D255N on NM_018223.2) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1341253353, COSV57172291, COSV99905161; called by muse, mutect2, varscan2
- CHRNA7 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs201538174, COSV60970440; called by mutect2, varscan2
- CKAP2L | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV100198538; called by muse, mutect2, varscan2
- CLDN12 | c.433A>T p.T145S | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99842048; called by muse, mutect2
- CLEC7A | c.339A>T p.T113= | Splice Region (SNP) | VAF 33/129 reads (26%) | catalogued as COSV100021092; called by muse, mutect2, varscan2
- CLIP3 | c.870C>A p.S290R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.237); catalogued as COSV100859306; called by muse, mutect2, varscan2
- CMIP | c.1189G>C p.V397L (on ENST00000537098 / NM_198390.2; = p.V303L on NM_030629.3) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.911); catalogued as COSV101220875; called by muse, mutect2, varscan2
- CNOT1 | c.5734C>T p.R1912C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765229031, COSV99799763; called by muse, mutect2, varscan2
- CNOT3 | c.25+1G>T p.X9_splice | Splice Site (SNP) | VAF 21/108 reads (19%) | catalogued as COSV99651653; called by muse, mutect2, varscan2
- CNTNAP2 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100664598, COSV62264864; called by mutect2, varscan2
- COL19A1 | c.2057G>C p.G686A | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100505870; called by muse, mutect2, varscan2
- COL1A1 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs990375606, COSV56803771; called by muse, mutect2, varscan2
- CPAMD8 | c.1255G>T p.D419Y (on ENST00000651564; = p.D372Y on NM_015692.5) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370768920, COSV52231899, COSV99359178; called by muse, mutect2, varscan2
- CPB2 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | catalogued as COSV99473025; called by muse, mutect2, varscan2
- CPNE6 | c.568G>C p.V190L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV99393258; called by muse, mutect2, varscan2
- CPO | c.975G>T p.Q325H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99786432; called by muse, mutect2, varscan2
- CRACD | c.3475G>A p.A1159T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as rs755984041, COSV99948939; called by muse, mutect2, varscan2
- CRYGN | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.029); catalogued as COSV100484719; called by muse, mutect2, varscan2
- CTCF | c.1481G>T p.R494L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV50531798, COSV99864894; called by muse, mutect2, varscan2
- CTNND2 | c.2662G>C p.V888L | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100474515; called by muse, mutect2, varscan2
- CUL4B | c.1292A>C p.Y431S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100340314; called by muse, mutect2, varscan2
- CYP26B1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV50010691, COSV99134414; called by muse, mutect2, varscan2
- CYP3A4 | c.1438C>A p.L480I (on ENST00000336411; = p.L449I on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100315554; called by muse, mutect2, varscan2
- CYP4F3 | c.1546G>C p.V516L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as COSV99658024; called by muse, mutect2, varscan2
- DBT | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100923452; called by muse, mutect2, varscan2
- DBX2 | c.449C>A p.A150E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs377142325, COSV100224268; called by mutect2, varscan2
- DCAF16 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.959); catalogued as COSV101200413; called by muse, mutect2, varscan2
- DCDC1 | c.2326C>G p.L776V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as COSV100663064; called by muse, mutect2, varscan2
- DCLRE1C | c.665A>T p.E222V (on ENST00000378278 / NM_001350965.2; = p.E107V on NM_022487.4) | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100739772; called by muse, varscan2
- DEPDC4 | c.346T>C p.S116P | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.813); catalogued as COSV100147290; called by muse, mutect2, varscan2
- DHRS7C | c.577G>T p.A193S (on ENST00000330255 / NM_001220493.2; = p.A192S on NM_001105571.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV100364508, COSV100364616; called by muse, mutect2, varscan2
- DNAH8 | c.7772C>A p.T2591N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV100544150; called by muse, mutect2, varscan2
- DNASE2 | c.268-1G>C p.X90_splice | Splice Site (SNP) | VAF 16/91 reads (18%) | catalogued as COSV53434776, COSV99322353; called by muse, mutect2, varscan2
- DOCK11 | c.6100C>T p.Q2034* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as COSV99353408; called by muse, mutect2, varscan2
- DOK6 | c.602T>C p.M201T | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV101234383; called by muse, mutect2, varscan2
- DPPA4 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100169334; called by muse, varscan2
- DYSF | c.2705C>A p.P902H | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as COSV99245726; called by muse, mutect2, varscan2
- EPHA6 | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV101061624; called by muse, mutect2, varscan2
- EPHA6 | c.2881T>A p.W961R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101061626; called by muse, mutect2, varscan2
- ERBB2 | c.3700C>T p.P1234S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV99507387; called by muse, mutect2, varscan2
- FAT1 | c.1588A>T p.M530L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.75); catalogued as COSV101499234; called by muse, mutect2, varscan2
- FER1L5 | c.3899T>A p.L1300Q (on ENST00000623019; = p.L1273Q on NM_001293083.2) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV101208834; called by muse, mutect2, varscan2
- FGF10 | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as CM060991, COSV99240358; called by muse, mutect2, varscan2
- FRMD7 | c.1577C>A p.T526N | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV100048822; called by muse, mutect2, varscan2
- FRMPD4 | c.1768A>G p.K590E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.084); catalogued as COSV101042544; called by muse, mutect2, varscan2
- FRZB | c.517del p.A173Qfs*34 | Frame Shift Del (DEL) | VAF 27/138 reads (20%) | catalogued as COSV54556005; called by mutect2, pindel, varscan2
- FSHR | c.2059G>C p.V687L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.169); catalogued as COSV100436850; called by muse, mutect2, varscan2
- FSHR | c.23T>C p.L8S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100436852; called by muse, mutect2, varscan2
- FSTL5 | c.1630C>G p.P544A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100053962; called by muse, mutect2, varscan2
- FUT9 | c.970G>C p.V324L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV100133338; called by muse, mutect2, varscan2
- GALC | c.1933C>G p.L645V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV99729364; called by muse, mutect2, varscan2
- GALNT11 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs779220999, COSV100231727; called by muse, mutect2, varscan2
- GBP1 | c.874+1G>T p.X292_splice | Splice Site (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100976242; called by muse, mutect2, varscan2
- GLB1L2 | c.1277A>T p.Q426L | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV100335249; called by muse, mutect2, varscan2
- GPR158 | c.2456G>T p.S819I | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100893132; called by muse, mutect2, varscan2
- GRIA2 | c.2234G>T p.G745V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99643815; called by muse, mutect2, varscan2
- GRM1 | c.1861C>A p.P621T | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99265209; called by muse, mutect2, varscan2
- GTF3C3 | c.1007A>G p.Y336C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs138093114; called by muse, mutect2
- GZF1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs767723250, COSV100582463; called by muse, mutect2, varscan2
- HAUS5 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99067949, COSV99178005; called by muse, mutect2, varscan2
- HID1 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); catalogued as COSV100585972; called by muse, mutect2, varscan2
- HSPH1 | c.2477A>G p.E826G | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100184797; called by muse, mutect2, varscan2
- HTR1E | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100541026; called by muse, mutect2, varscan2
- IGKV6D-41 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs371541946; called by muse, mutect2, varscan2
- IQUB | c.658G>C p.D220H | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100226939; called by muse, mutect2, varscan2
- ITM2A | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs759552531, COSV100964435, COSV64810818; called by muse, mutect2, varscan2
- KLC3 | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV101228855; called by muse, mutect2, varscan2
- KMT2C | c.13056G>A p.W4352* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV51435536; called by muse, mutect2, varscan2
- LCMT2 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as rs771976433, COSV99979999; called by muse, mutect2, varscan2
- LPIN2 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99858157; called by muse, mutect2, varscan2
- LRRC4C | c.1136C>A p.T379K | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.667); catalogued as rs748255377, COSV99537628; called by muse, mutect2, varscan2
- LRRK2 | c.5019G>T p.L1673F | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1323591086, COSV100109070, COSV100109697; called by muse, mutect2, varscan2
- LRRK2 | c.5899A>T p.T1967S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as COSV100109698; called by muse, mutect2, varscan2
- LSG1 | c.1774G>A p.V592I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); catalogued as rs370609808; called by muse, mutect2, varscan2
- LZTS1 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as rs376917114; called by muse, mutect2, varscan2
- MAEL | c.365G>T p.S122I | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100901765; called by muse, mutect2, varscan2
- MAGEB6 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as rs747759841, COSV100983696, COSV100983698; called by muse, mutect2, varscan2
- MAGEC1 | c.2029C>A p.Q677K | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99595332; called by muse, mutect2, varscan2
- MAP4K3 | c.1766A>G p.N589S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99810190; called by muse, mutect2, varscan2
- MAPK4 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68541333; called by muse, mutect2, varscan2
- MATK | c.281G>T p.S94I (on ENST00000310132 / NM_139355.3; = p.S95I on NM_002378.4) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV100035954; called by muse, mutect2, varscan2
- MAVS | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.653); catalogued as rs200118692; called by muse, mutect2, varscan2
- MDH1B | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100982161; called by muse, mutect2, varscan2
- MED26 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as rs1322713308, COSV99659894; called by muse, mutect2, varscan2
- MEGF11 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.676); catalogued as COSV99987330; called by muse, mutect2, varscan2
- MMRN1 | c.1579T>A p.S527T | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99306835; called by muse, mutect2, varscan2
- MPL | c.211C>A p.R71= | Splice Region (SNP) | VAF 8/46 reads (17%) | catalogued as rs780738649, COSV100991468, COSV65244214; called by muse, varscan2
- MRGPRD | c.266C>A p.P89H | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.117); catalogued as rs1451359882, COSV100482967; called by muse, mutect2, varscan2
- MRPL54 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV100349619; called by muse, mutect2, varscan2
- MTMR10 | c.717G>T p.W239C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100076039; called by muse, mutect2, varscan2
- MYT1L | c.3361A>G p.N1121D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV101217011, COSV67702858; called by muse, mutect2, varscan2
- NAALAD2 | c.1317T>A p.Y439* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100428219; called by muse, mutect2, varscan2
- NAV3 | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.469); catalogued as rs1156907822, COSV99888923; called by muse, mutect2, varscan2
- NDNF | c.1163A>T p.Q388L | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV101113136; called by muse, mutect2, varscan2
- NDUFB9 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs774728394, COSV99412712; called by muse, mutect2, varscan2
- NFATC2 | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV101043873; called by muse, mutect2, varscan2
- NIPA1 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100507790, COSV61679626; called by muse, mutect2, varscan2
- NLGN1 | c.1592A>G p.N531S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as rs944429237, COSV100849040; called by muse, mutect2, varscan2
- NLN | c.2032G>T p.G678C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101114191; called by muse, mutect2, varscan2
- NLRP12 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.515); catalogued as rs760475376, COSV100145072; called by muse, mutect2, varscan2
- NMUR1 | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100531883; called by muse, mutect2, varscan2
- NPLOC4 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100480775; called by muse, mutect2, varscan2
- NPLOC4 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100480780; called by muse, mutect2, varscan2
- NRXN1 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100454238; called by muse, varscan2
- NSD1 | c.6025G>A p.A2009T | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100728691; called by muse, mutect2, varscan2
- NSD2 | c.1628A>T p.D543V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.1); catalogued as COSV100373025; called by muse, mutect2, varscan2
- OR10A3 | c.812A>G p.K271R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs199512370, COSV100660246; called by muse, mutect2, varscan2
- OR10A5 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100203403, COSV55055957; called by muse, mutect2, varscan2
- OR10A7 | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV100406535; called by muse, mutect2, varscan2
- OR10G8 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV101461817, COSV101461902; called by muse, varscan2
- OR10G8 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs756655164, COSV70908457; called by muse, varscan2
- OR2B2 | c.872C>T p.T291I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100308080; called by muse, mutect2, varscan2
- OR2T1 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV100822280; called by muse, mutect2, varscan2
- OR52D1 | c.162G>C p.M54I | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100495198; called by muse, mutect2, varscan2
- OR56A1 | c.536A>T p.N179I | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100360435, COSV57363553; called by muse, mutect2, varscan2
- OR56A3 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100290119, COSV61568435; called by muse, mutect2, varscan2
- OR5B12 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100222383; called by muse, varscan2
- OSBPL1A | c.2262C>G p.H754Q (on ENST00000319481 / NM_080597.4; = p.H241Q on NM_018030.4) | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768357149, COSV100111438; called by muse, mutect2, varscan2
- PAGE3 | c.46G>C p.D16H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100891977, COSV66586761; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1126G>C p.V376L (on ENST00000259318 / NM_001136562.3; = p.V607L on NM_007203.5) | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99394975; called by muse, mutect2, varscan2
- PCDHA1 | c.2366C>G p.P789R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV100974330, COSV100974338; called by muse, mutect2, varscan2
- PCDHGA2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); catalogued as COSV99534674; called by muse, mutect2, varscan2
- PEAK1 | c.3883A>T p.T1295S | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100432741; called by muse, mutect2, varscan2
- PEG3 | c.960G>C p.K320N | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV99688197; called by muse, mutect2, varscan2
- PHF3 | c.5148A>T p.L1716F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100013120; called by muse, mutect2, varscan2
- PLCB1 | c.2596C>A p.H866N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100570154, COSV62072431; called by muse, mutect2, varscan2
- PLEKHG2 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs373554388; called by muse, mutect2, varscan2
- PLEKHG2 | c.1964G>T p.R655L | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.013); catalogued as COSV99217148; called by muse, mutect2, varscan2
- POLH | c.1785G>T p.M595I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100947721; called by muse, mutect2, varscan2
- POLQ | c.2933A>G p.Q978R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99951969; called by muse, mutect2, varscan2
- PRAMEF2 | c.937C>A p.L313I | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99535054; called by muse, mutect2, varscan2
- PRSS54 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99541531; called by muse, mutect2, varscan2
- PRUNE2 | c.6186G>T p.Q2062H | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100944378; called by muse, mutect2, varscan2
- PSD | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV50043129, COSV99192339; called by mutect2, varscan2
- PSG11 | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100105647; called by muse, mutect2, varscan2
- PTPRS | c.3157A>T p.S1053C | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV99509838; called by muse, mutect2, varscan2
- PYDC1 | c.232A>G p.M78V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV100265376; called by muse, mutect2, varscan2
- RASAL1 | c.1994C>A p.S665* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99921578; called by muse, mutect2
- RASSF3 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV99309297; called by muse, mutect2, varscan2
- RBX1 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99345374; called by muse, mutect2, varscan2
- RELN | c.2531C>G p.P844R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as CM155181, COSV100633129, COSV59030327; called by muse, mutect2, varscan2
- RIN3 | c.2179C>G p.L727V | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99378908; called by muse, mutect2, varscan2
- RNF135 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.735); catalogued as COSV100104005; called by muse, mutect2
- RSRP1 | c.26G>T p.W9L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as COSV99682605; called by muse, mutect2, varscan2
- SFRP4 | c.586A>G p.S196G | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as rs112054297, COSV101460881; called by muse, mutect2, varscan2
- SGCE | c.245C>A p.S82Y (on ENST00000647096; = p.S46Y on NM_003919.3) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1192695015, COSV99722345; called by muse, mutect2, varscan2
- SHANK1 | c.2785C>A p.P929T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99520714; called by muse, mutect2
- SHPRH | c.2327G>T p.R776L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51604046, COSV99261771; called by muse, mutect2, varscan2
- SHPRH | c.2247A>C p.Q749H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99261775; called by muse, mutect2
- SIGLEC7 | c.1082C>A p.A361D | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs764828847, COSV99978596; called by muse, mutect2, varscan2
- SLC41A3 | c.1121C>A p.S374* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as COSV100259500; called by muse, mutect2, varscan2
- SLC45A4 | c.256T>C p.Y86H (on ENST00000517878 / NM_001286646.2; = p.Y35H on NM_001080431.2) | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99196759; called by muse, mutect2, varscan2
- SLC4A2 | c.1828G>T p.V610L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as COSV100055130, COSV59657156; called by muse, mutect2
- SLC6A12 | c.602C>A p.S201* | Nonsense Mutation (SNP) | VAF 31/117 reads (26%) | catalogued as COSV100675036; called by muse, mutect2, varscan2
- SLC7A9 | c.644A>G p.Q215R | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1222709323, COSV99195250; called by muse, mutect2, varscan2
- SMC3 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100699863; called by muse, varscan2
- SNAP91 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99534874; called by muse, mutect2, varscan2
- SNPH | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100378058; called by muse, mutect2, varscan2
- SNX6 | c.485G>A p.R162H (on ENST00000652385; = p.R34H on NM_021249.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs762864087, COSV100751411; called by mutect2, varscan2
- SPATA19 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100141071, COSV54483514; called by muse, mutect2, varscan2
- SPATA31A1 | c.2014G>T p.G672W | Missense Mutation (SNP) | VAF 69/484 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422702658; called by muse, mutect2, varscan2
- SRCAP | c.6679G>A p.E2227K | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV52667731, COSV99049146; called by muse, mutect2, varscan2
- SRXN1 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV101126497; called by muse, mutect2, varscan2
- STYXL2 | c.3109C>T p.P1037S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99608881; called by muse, mutect2, varscan2
- SYNDIG1 | c.312C>A p.D104E | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100965219, COSV65235246; called by muse, mutect2, varscan2
- SZT2 | c.6316C>T p.R2106W (on ENST00000634258 / NM_001365999.1; = p.R2049W on NM_015284.4) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs769396036, COSV100987023; called by muse, mutect2, varscan2
- TACC1 | c.2117A>C p.K706T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99393295; called by muse, mutect2, varscan2
- TBC1D17 | c.1543G>T p.V515L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99680538; called by muse, mutect2, varscan2
- TEP1 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.916); catalogued as COSV52998310, COSV99401997; called by muse, mutect2, varscan2
- TEX9 | c.557A>T p.N186I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV100771371; called by muse, varscan2
- TGIF2LX | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV99383255; called by muse, mutect2, varscan2
- TGOLN2 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 136/534 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV99965001; called by muse, mutect2, varscan2
- THSD7B | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55649265, COSV99747659; called by muse, mutect2, varscan2
- THSD7B | c.1117A>G p.I373V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs766882283, COSV55681710; called by muse, mutect2, varscan2
- TKTL2 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV99761264; called by muse, mutect2, varscan2
- TMEM200C | c.1702C>A p.L568M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV101274805; called by muse, mutect2, varscan2
- TMEM61 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs775542202, COSV64874070; called by muse, mutect2, varscan2
- TNFRSF19 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99947258; called by muse, mutect2
- TNR | c.3070A>G p.T1024A | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV99688726; called by muse, mutect2, varscan2
- TRIM3 | c.1055G>C p.G352A | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV100624321; called by muse, mutect2, varscan2
- TTN | c.89335G>A p.V29779M (on ENST00000591111; = p.V22355M on NM_003319.4) | Missense Mutation (SNP) | VAF 44/170 reads (26%) | PolyPhen possibly damaging (0.684); catalogued as COSV100603223; called by muse, varscan2
- TTN | c.53452G>A p.V17818M (on ENST00000591111; = p.V10394M on NM_003319.4) | Missense Mutation (SNP) | VAF 45/200 reads (23%) | PolyPhen probably damaging (0.98); catalogued as COSV100603224; called by muse, mutect2, varscan2
- TTN | c.28217G>T p.G9406V (on ENST00000591111; = p.G8479V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/136 reads (24%) | PolyPhen probably damaging (1); catalogued as COSV100603227; called by muse, mutect2, varscan2
- TTN | c.16717A>T p.S5573C (on ENST00000591111; = p.S4646C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/234 reads (26%) | PolyPhen probably damaging (0.935); catalogued as COSV100603229; called by muse, mutect2, varscan2
- TUFT1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs750454205, COSV100777046; called by muse, mutect2, varscan2
- UBQLN3 | c.353C>A p.P118H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100293518; called by muse, mutect2, varscan2
- UNC5C | c.1349G>C p.R450T | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as COSV101497840, COSV71662460; called by muse, mutect2, varscan2
- UPK3A | c.572-2A>T p.X191_splice | Splice Site (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99343085; called by muse, mutect2, varscan2
- USH2A | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780026683, COSV100232278; called by mutect2, varscan2
- USP54 | c.3494C>T p.P1165L | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100357250; called by muse, mutect2, varscan2
- USP6NL | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs374849121, COSV53213224; called by muse, mutect2, varscan2
- VIRMA | c.5422C>T p.R1808C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs750028172, COSV52587134; called by muse, mutect2, varscan2
- VPS13C | c.4546G>T p.D1516Y (on ENST00000644861 / NM_020821.3; = p.D1473Y on NM_017684.5) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV99827918; called by muse, mutect2, varscan2
- WASHC3 | c.358A>G p.S120G | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99527437; called by muse, mutect2, varscan2
- WDR11 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV99676414; called by muse, mutect2, varscan2
- WDR77 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs374674543; called by muse, mutect2
- WNK4 | c.478A>G p.M160V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780436160, COSV99519380; called by muse, mutect2, varscan2
- XPNPEP3 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100846660; called by muse, mutect2, varscan2
- ZBED9 | c.682A>T p.R228* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV101509184; called by muse, mutect2, varscan2
- ZNF140 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100166825; called by muse, mutect2, varscan2
- ZNF44 | c.718G>T p.G240C (on ENST00000356109 / NM_001164276.2; = p.G192C on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100633526; called by muse, mutect2, varscan2
- ZNF792 | c.1290C>G p.F430L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV101289684; called by muse, mutect2, varscan2
- ZNF804B | c.3983G>A p.C1328Y | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100302844; called by muse, mutect2, varscan2
- ZNF875 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as COSV100183194; called by muse, mutect2, varscan2
- ZW10 | c.575C>G p.S192* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99562562; called by muse, mutect2, varscan2
- ABCA7 | c.5369_5374del p.G1790_D1791del | In Frame Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- ALPK1 | c.1111dup p.E371Gfs*13 | Frame Shift Ins (INS) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- CRLF1 | c.950del p.G317Afs*109 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- DPF2 | c.980del p.C327Sfs*52 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by pindel, varscan2
- DUS3L | c.1220del p.G407Afs*5 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- IGHV4-34 | c.29A>T p.H10L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MPZL3 | c.72_73+1delinsT p.X24_splice | Splice Site (DEL) | VAF 23/153 reads (15%) | called by pindel, varscan2*
- NCOA4 | c.1670A>T p.D557V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SPPL2C | c.625del p.E209Kfs*47 | Frame Shift Del (DEL) | VAF 31/99 reads (31%) | called by mutect2, pindel, varscan2
- TMEM170B | c.200del p.G67Efs*17 | Frame Shift Del (DEL) | VAF 29/180 reads (16%) | called by mutect2, pindel, varscan2
- TRAV12-3 | c.152C>G p.A51G | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF253 | c.867_868del p.C289Wfs*5 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | called by pindel, varscan2
- ADAMTS18 | c.2499G>C p.A833= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV51415536, COSV99271901; called by muse, mutect2, varscan2
- AHNAK2 | c.11574C>T p.A3858= | Silent (SNP) | VAF 59/263 reads (22%) | catalogued as rs778476413; called by muse, mutect2, varscan2
- ALPP | c.1278C>T p.G426= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV67397178, COSV67398338; called by muse, mutect2
- ANKS1B | c.1662A>T p.T554= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV101612648; called by muse, mutect2, varscan2
- ANO4 | c.1275A>T p.G425= (on ENST00000392977 / NM_001286615.2; = p.G390= on NM_178826.4) | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100152501; called by muse, mutect2, varscan2
- ASXL3 | c.327G>A p.E109= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99324169; called by muse, mutect2, varscan2
- CACNG6 | c.627G>T p.P209= (on ENST00000252729 / NM_145814.1; = p.P138= on NM_031897.2) | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV53167649, COSV99403347; called by muse, mutect2, varscan2
- CAMK4 | c.1257G>A p.K419= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV99998766; called by muse, mutect2, varscan2
- CDK2AP2 | c.177G>T p.V59= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100039363; called by muse, mutect2, varscan2
- CEP290 | c.3216G>T p.R1072= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100468258; called by muse, mutect2, varscan2
- CFAP251 | c.1818G>A p.K606= | Silent (SNP) | VAF 41/181 reads (23%) | catalogued as rs1235673996, COSV56608526; called by muse, mutect2, varscan2
- CHST6 | c.198C>G p.V66= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as CD033185, COSV100178340; called by muse, varscan2
- COL6A6 | c.2160C>A p.P720= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as COSV100650106; called by muse, mutect2, varscan2
- COX7A2L | c.153G>T p.V51= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV99309915; called by muse, mutect2, varscan2
- CRB1 | c.2304G>A p.E768= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV100957763; called by muse, mutect2, varscan2
- CYP4V2 | c.711C>T p.P237= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV66506494; called by muse, mutect2, varscan2
- DMBT1 | c.924C>T p.S308= | Silent (SNP) | VAF 67/202 reads (33%) | catalogued as rs757020107, COSV100352579; called by muse, mutect2, varscan2
- ERCC3 | c.1594T>C p.L532= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99573193; called by muse, mutect2, varscan2
- EXPH5 | c.2619G>T p.S873= | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV99761277; called by muse, mutect2, varscan2
- FCRL5 | c.486T>G p.G162= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100708735; called by muse, mutect2, varscan2
- FOXR1 | c.522C>G p.P174= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV100392858, COSV57651180; called by muse, mutect2, varscan2
- FRMD7 | c.1578T>C p.T526= | Silent (SNP) | VAF 70/207 reads (34%) | catalogued as COSV100048819; called by muse, mutect2, varscan2
- FSHB | c.129C>T p.T43= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV54221874, COSV99569362; called by muse, mutect2, varscan2
- GABRA5 | c.801C>G p.P267= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100164950, COSV59479703; called by muse, mutect2, varscan2
- HERC5 | c.2157G>A p.G719= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs955498125, COSV99987561; called by muse, mutect2, varscan2
- IDH3B | c.900C>T p.Y300= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as rs201237064; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF1R | c.357C>A p.I119= | Silent (SNP) | VAF 36/62 reads (58%) | catalogued as COSV99151009; called by muse, mutect2, varscan2
- IGKV2D-24 | c.24G>A p.L8= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1290476162; called by mutect2, varscan2
- IL10RA | c.879C>A p.I293= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV99922960; called by muse, mutect2, varscan2
- ILDR2 | c.756T>A p.G252= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99613550; called by muse, mutect2, varscan2
- INTS1 | c.5274C>T p.I1758= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV101247686; called by muse, mutect2
- KCNMA1 | c.498G>T p.A166= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV54248348, COSV99696192; called by muse, mutect2, varscan2
- KIF2B | c.627G>C p.P209= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV52130240, COSV99275032; called by muse, mutect2, varscan2
- LAMA2 | c.7695G>A p.L2565= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV101370290, COSV70337902; called by muse, mutect2, varscan2
- MAGEC1 | c.2028C>A p.L676= | Silent (SNP) | VAF 47/146 reads (32%) | catalogued as rs1404270625, COSV53570580, COSV99595329; called by muse, mutect2, varscan2
- MKRN3 | c.381C>G p.A127= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100090991, COSV58810037; called by muse, mutect2, varscan2
- MRPL10 | c.600G>A p.L200= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs1293963994, COSV99136627; called by muse, mutect2, varscan2
- MXRA5 | c.6945G>A p.G2315= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as COSV54241353, COSV99476332; called by muse, mutect2, varscan2
- NLRP12 | c.1638C>G p.T546= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as COSV100145075, COSV60743457; called by muse, mutect2, varscan2
- NRXN1 | c.1377A>T p.G459= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as COSV58473311; called by muse, varscan2
- NTRK3 | c.1350C>T p.F450= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV58122720; called by muse, mutect2, varscan2
- NUTM1 | c.1038G>C p.R346= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV100148929; called by muse, mutect2, varscan2
- OLR1 | c.309G>A p.K103= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as rs146929021; called by muse, mutect2, varscan2
- OPTC | c.963C>T p.F321= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV100921759; called by muse, mutect2, varscan2
- OR9G1 | c.546C>T p.P182= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as rs766574995, COSV100380325; called by muse, mutect2, varscan2
- PCDHA6 | c.309C>T p.S103= | Silent (SNP) | VAF 68/290 reads (23%) | catalogued as rs1554131285, COSV100972199, COSV65355025; called by muse, varscan2
- PCDHAC2 | c.594G>A p.K198= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99145636; called by muse, mutect2, varscan2
- PKD2L1 | c.192C>A p.T64= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100559347; called by muse, mutect2, varscan2
- PROX1 | c.1416C>A p.T472= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as COSV99799003; called by muse, mutect2, varscan2
- RHOB | c.438C>A p.A146= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as rs1203444708, COSV99695187; called by muse, mutect2, varscan2
- RHOBTB1 | c.738A>T p.P246= | Silent (SNP) | VAF 43/186 reads (23%) | catalogued as COSV100558406; called by muse, mutect2, varscan2
- RHPN1 | c.342G>T p.L114= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV100000559; called by muse, mutect2, varscan2
- SCN8A | c.1944G>T p.V648= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV100633579; called by muse, mutect2, varscan2
- SH3TC2 | c.1773G>T p.L591= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100101458; called by muse, mutect2, varscan2
- SLC4A3 | c.2427C>T p.A809= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as rs1178659992, COSV56094903; called by muse, mutect2, varscan2
- SLCO1A2 | c.522C>A p.P174= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100261582; called by muse, mutect2, varscan2
- TKTL1 | c.162T>A p.S54= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99473854; called by muse, mutect2, varscan2
- TLR8 | c.2130T>C p.F710= (on ENST00000218032 / NM_138636.5; = p.F728= on NM_016610.4) | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as COSV99486906; called by muse, mutect2, varscan2
- TRBV4-2 | c.333C>A p.A111= | Silent (SNP) | VAF 42/361 reads (12%) | called by muse, mutect2, varscan2
- TTC7B | c.1770G>A p.V590= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV100127666; called by muse, mutect2, varscan2
- TTN | c.89541T>A p.A29847= (on ENST00000591111; = p.A22423= on NM_003319.4) | Silent (SNP) | VAF 52/246 reads (21%) | catalogued as COSV100603222; called by muse, varscan2
- TTN | c.24618C>A p.A8206= (on ENST00000591111; = p.A7279= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100603228; called by muse, mutect2, varscan2
- VNN1 | c.834C>A p.G278= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100907700; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848637 G>T | 5'Flank (SNP) | VAF 9/26 reads (35%) | called by muse, varscan2
- MIR382 | n.56C>A | RNA (SNP) | VAF 10/23 reads (43%) | called by muse, varscan2
- MIR551B | n.74G>C | RNA (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671144 G>A | 3'Flank (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- TNFSF10 | c.-1C>T | 5'UTR (SNP) | VAF 18/107 reads (17%) | catalogued as COSV99577650; called by muse, mutect2, varscan2
